Gene-level copy-number profile of tumor specimen MP2PRT-PASRGI-TBP1-A from MP2PRT case MP2PRT-PASRGI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,328 days).
Specimen MP2PRT-PASRGI-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 552323ed-8d6f-40e6-a004-f59576a8dba6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASRGI-NM1-B (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/5b68c080-8863-468f-95cc-6729382a12a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 157; copy number 1: 227; copy number 2: 36,961; copy number 3: 17,999; copy number 4: 2,264; copy number 5: 753; copy number 7: 6.

Homozygous deletions (total copy number 0; autosomes only): 157 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,192,500–89,295,455, 13 genes (within-gene range 0–1): IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr8:7,200,756–7,200,857, 1 gene: AF228730.1.
- chr8:12,064,389–12,115,516, 4 genes: DEFB130B, RNA5SP253, DEFB108D, ZNF705D.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:20,658,309–23,438,700, 64 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:41,131,306–41,573,606, 12 genes (within-gene range 0–1): CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70.
- chr9:64,810,865–65,193,610, 5 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–3): TRDD1, TRDD2.
- chr14:105,851,705–106,122,709, 52 genes (within-gene range 0–3): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–3): IGHVIII-16-1.
- chr20:30,214,765–30,214,976, 1 gene: CFTRP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 759 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,333,644–12,388,296, 6 genes, copy number 7: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr8:141,514,638–143,083,001, 41 genes, copy number 5: AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L.
- chr21:13,305,152–33,170,649, 346 genes, copy number 5 (broad region; genes not listed).
- chr21:33,403,413–46,691,226, 366 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
